Somatic mutation profile of tumor specimen C3L-05866-54 (aliquot CPT0451240002) from CPTAC case C3L-05866, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 73.5 years (26,829 days).
Specimen C3L-05866-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20e28748-6b3a-4b83-bf74-19aad155feb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05866-51 (Buccal Cell Normal), aliquot CPT0451210002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8163a278-f502-4f31-b009-e4cbe9c1d6d8

The open-access MAF lists 25 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 4, 3'UTR 1, Frame Shift Ins 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 83/199 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 20/80 reads (25%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 47/371 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADCY10 | c.1156G>A p.V386I | Missense Mutation (SNP) | VAF 142/296 reads (48%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.997); catalogued as rs779872352; called by muse, mutect2, varscan2
- ASPG | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374851348; called by muse, mutect2, varscan2
- GPT | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 104/260 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); catalogued as rs1257281084; called by muse, mutect2, varscan2
- GRB7 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as rs780450400, COSV58450783; called by muse, mutect2
- GULP1 | c.202C>G p.P68A | Missense Mutation (SNP) | VAF 63/132 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as COSV63076583; called by muse, mutect2, varscan2
- ITGB7 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 166/357 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.921); catalogued as rs372408845; called by muse, mutect2, varscan2
- MSI1 | c.77del p.G26Dfs*21 | Frame Shift Del (DEL) | VAF 68/176 reads (39%) | catalogued as rs1490523146; called by mutect2, pindel, varscan2
- THAP12 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | catalogued as rs746861158; called by muse, varscan2
- TKTL2 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54917577; called by muse, mutect2, varscan2
- TMEM132D | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 104/233 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.914); catalogued as rs775400147; called by muse, mutect2, varscan2
- TRPM8 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 139/317 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs763830658; called by muse, mutect2, varscan2
- TRPV6 | c.2080C>T p.R694W | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); catalogued as rs374556937; called by muse, mutect2, varscan2
- DNAH2 | c.4750G>A p.V1584M | Missense Mutation (SNP) | VAF 82/176 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- NIBAN1 | c.947T>C p.I316T | Missense Mutation (SNP) | VAF 102/212 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PKD1 | c.4971G>C p.R1657S | Missense Mutation (SNP) | VAF 252/562 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.081); called by mutect2, varscan2
- RIMS1 | c.1937T>C p.V646A | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ZSWIM3 | c.38T>A p.F13Y | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- C12orf40 | c.1080G>A p.S360= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as rs774419398, COSV61129207; called by muse, mutect2, varscan2
- HECA | c.381C>G p.T127= | Silent (SNP) | VAF 103/227 reads (45%) | called by muse, mutect2, varscan2
- LAX1 | c.324G>A p.S108= | Silent (SNP) | VAF 63/228 reads (28%) | catalogued as rs763047190, COSV65849277; called by muse, mutect2, varscan2
- TTC39B | c.508T>C p.L170= | Silent (SNP) | VAF 40/94 reads (43%) | called by muse, mutect2, varscan2
- INHA | c.*5_*11dup | 3'UTR (INS) | VAF 24/120 reads (20%) | called by mutect2, varscan2
